Gene-level copy-number profile of tumor specimen C3L-04013-05 from CPTAC case C3L-04013, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 61.6 years (22,508 days).
Specimen C3L-04013-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 14244bab-84c1-4845-a7aa-d9bd87282d33.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04013-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/6fc1a9bd-8524-40dc-8e76-a3ec3410415f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 23; copy number 2: 14,746; copy number 3: 26,221; copy number 4: 10,853; copy number 5: 2,636; copy number 6: 2,916; copy number 7: 580; copy number 8: 551; copy number 9: 42; copy number 10: 82; copy number 11: 47; copy number 12: 2; copy number 13: 15; copy number 14: 3; copy number 16: 11; copy number 17: 45; copy number 19: 25; copy number 20: 32; copy number 31: 3; copy number 33: 4; copy number 76: 2; copy number 78: 5; copy number 79: 4; copy number 81: 2; copy number 82: 12; copy number 83: 3; copy number 89: 1; copy number 94: 3.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–6): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr8:12,064,389–12,177,550, 10 genes (within-gene range 0–3): DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr13:81,018,176–81,044,691, 1 gene: LINC00377.
- chr13:100,089,015–101,720,856, 16 genes (within-gene range 0–3): PCCA, RPL15P18, AL356575.1, AL353697.1, PCCA-AS1, GGACT, AL356966.1, AL136526.1, RPS26P47, TMTC4, COX5BP6, NALCN-AS1, ARF4P3, LINC00411, NALCN, ITGBL1.
- chr13:101,717,564–101,802,488, 3 genes (within-gene range 0–3): AL160153.1, RNU1-24P, HMGB3P7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,474 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:35,617,844–35,814,611, 1 gene, copy number 8 (within-gene range 6–8): SPEF2.
- chr5:35,678,484–39,889,059, 72 genes, copy number 7–8 (broad region; genes not listed).
- chr7:22,854,126–23,177,914, 8 genes, copy number 7: SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3.
- chr12:16,420,653–16,788,375, 6 genes, copy number 79–81 (within-gene range 3–81): AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1.
- chr12:24,967,127–25,250,936, 11 genes, copy number 82: BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:47,661,249–47,742,294, 5 genes, copy number 78 (within-gene range 3–78): RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5.
- chr12:123,410,683–123,473,154, 3 genes, copy number 76–82 (within-gene range 5–82): RILPL2, COPS5P2, SNRNP35.
- chr13:59,262,680–64,076,044, 43 genes, copy number 12–20: RPP40P2, RNU7-88P, DIAPH3, DIAPH3-AS1, RN7SL375P, DIAPH3-AS2, RNY4P28, LINC00434, TARDBPP2, AL359920.1, TDRD3, RNA5SP31, LINC00378, EIF4A1P6, AL161901.1, RNY3P5, LINC01442, MIR3169, PCDH20, AL592490.1, LINC02339, RAC1P8, AL353765.1, LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, LINC00448, AL354810.1, LINC00376, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, OR7E104P, AL445238.1, LINC00355, NFYAP1.
- chr13:68,634,190–68,893,573, 5 genes, copy number 8: RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342.
- chr13:69,101,832–71,867,204, 16 genes, copy number 7–14 (within-gene range 6–14): SNRPFP3, LINC00383, SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P, AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109.
- chr13:72,453,902–77,764,242, 72 genes, copy number 7–13 (broad region; genes not listed).
- chr13:83,877,205–92,873,682, 74 genes, copy number 9–33 (within-gene range 4–33) (broad region; genes not listed).
- chr13:102,292,327–102,394,519, 3 genes, copy number 7 (within-gene range 3–7): FGF14-IT1, AL356266.1, FGF14-AS1.
- chr13:102,589,372–107,867,496, 42 genes, copy number 7–94 (within-gene range 6–94): LINC00555, AL158063.1, TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2, SLC10A2, LINC01309, ATP6V1G1P7, RPL7P45, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, RNA5SP38, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL162574.2, PPIAP24, AL162574.1, AL162574.3, FAM155A, SNORD31B.
- chr13:107,531,171–107,531,248, 1 gene, copy number 9 (within-gene range 9–80): MIR1267.
- chr13:108,207,439–109,208,005, 9 genes, copy number 7–9: LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1.
- chr13:109,752,695–110,307,157, 12 genes, copy number 7–89 (within-gene range 3–89): IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, COL4A1, AL161773.1.
- chr13:110,613,082–113,928,991, 81 genes, copy number 8–31 (broad region; genes not listed).
- chr16:32,475,051–32,478,250, 1 gene, copy number 7: ABCD1P3.
- chr16:71,420,483–71,809,201, 24 genes, copy number 10: AC010547.6, TLE7, AC010547.5, ZNF23, AC010547.4, AC010547.1, ZNF19, AC010547.3, CHST4, AC010547.2, RNU6-1061P, TAT-AS1, TAT, AC009097.2, MARVELD3, PHLPP2, AC009097.1, RNU6-208P, SNORA70D, AC009097.4, AC009097.3, AP1G1, SNORD71, AC010653.3.
- chr18:158,383–1,310,018, 33 genes, copy number 7 (within-gene range 6–7): USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3.
- chr20:87,250–13,996,443, 277 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:30,214,765–39,349,392, 290 genes, copy number 7–8 (broad region; genes not listed).
- chr20:39,932,922–54,859,812, 323 genes, copy number 7–8 (broad region; genes not listed).
- chr20:57,105,741–59,259,113, 62 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
